FM case AD9526 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/f42e6315-911c-4607-b8e9-24fece65af1d

Female, 76.2 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the ovary; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
